Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A5VI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A5VI-01A (Primary Tumor).

[page 1 of 2]
ICD 0-3
Carcinoma, squamous cell
non-keratinizing NOS 8672/3
Site: Cervix NOS C53.9
JAN 4/4/13

PATIENT INFORMATION		UUID: 4ADC462C-2D78-4CAA-B865-5D954A080801 TCGA-JW-A5VI-01A-PR Redacted
SEX: F AGE:	DOB:	
SPECIMEN INFORMATION		
Collected: Received: Reported:	Accession #:	
CLINICAL INFORMATION		
SURGICAL PATHOLOGY REPORT		
IMAGES		
Microscopic images is a synthetic representation of the key findings of your specimen report. The image is not intended to replace a complete review and reading of the final diagnosis report.		
DIAGNOSIS		
CERVIX (BIOPSY): INVASIVE SQUAMOUS CELL CARCINOMA, NON-KERATINIZING TYPE, MODERATELY TO POORLY DIFFERENTIATED (GRADE 2-3/3). SEE COMMENTS.		
COMMENTS: The invasive squamous cell carcinoma involves all fragments submitted. One fragment shows ulcerated surface mucosa, overlying infiltrating tumor; adjacent intact benign squamous epithelium shows mild reactive changes. The invasive squamous carcinoma extends to peripheral and deep margins in all fragments. There is no evidence of unequivocal capillary-lymphatic space involvement. The tumor size approximates an area 1.2 x 0.3cm (lateral extent by depth). There is no previous abnormal pap smear available in our files for review with the current specimen. If this is in error, contact the laboratory to request a review. This case was reviewed as part of our These findings are discussed with _____ hesitate to contact me at _____ The report is FAXED. Please don't ask any questions regarding the pathologic findings.		
Electronic Signature:		
SPECIMEN DATA		
SPECIMENS: Cervical biopsy		
GROSS DESCRIPTION: The specimen container is labeled with the patient's name and "cervix". Received in formalin are multiple gray-white, irregular fragments of soft tissue collectively measuring 1.5 x 1.0 x 0.4 cm.		
FINAL REPORT		
PAGE 1 OF 2		

[page 2 of 2]
PATIENT INFORMATION

SPECIMEN INFORMATION

Accession #:

SURGICAL PATHOLOGY REPORT

SPECIMEN DATA

MICROSCOPIC DESCRIPTION:

Complete microscopic examination is performed.

H/PAA Discrepancy		☒

Source: NCI Genomic Data Commons file b91f2224-dab4-4f49-9031-2a887c239b81 (TCGA-JW-A5VI.4ADC462C-2D78-4CAA-B865-5D954A080801.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).